Somatic mutation profile of tumor specimen TCGA-XG-A823-01A (aliquot TCGA-XG-A823-01A-11D-A35I-08) from TCGA case TCGA-XG-A823, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 25.0 years (9,149 days).
Specimen TCGA-XG-A823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 490319c4-bb28-4109-9985-21c60ca17945.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XG-A823-10A (Blood Derived Normal), aliquot TCGA-XG-A823-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e992ee2-9dbc-4efc-9f30-c8197e8e59d1

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR1A | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FCRL3 | c.1362C>A p.D454E | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2
- FEZ1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- KMT2D | c.15842T>G p.L5281R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF18 | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- SESN1 | c.800G>C p.S267T (on ENST00000356644 / NM_001199933.1; = p.S326T on NM_014454.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- TIPARP | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- ANKFN1 | c.2247C>T p.L749= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- FANCM | c.4293A>G p.K1431= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- FCRL6 | c.252T>C p.S84= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- KANSL1 | c.609G>A p.G203= | Silent (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- OR6C6 | c.36C>G p.L12= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- GABRA3 | c.-26-27670G>A | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as rs376488461; called by muse, mutect2, varscan2
